Gene-level copy-number profile of tumor specimen ALCH-B2T2-TTP1-B from ALCHEMIST case ALCH-B2T2, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,156 days).
Specimen ALCH-B2T2-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3dfe9dba-4f1d-4265-8ffc-ef3c61462110.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T2-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/ab244bb9-9201-469a-b819-b3c12a773036

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 69; copy number 2: 54,875; copy number 3: 3,442; copy number 4: 7; copy number 5: 1; copy number 6: 3; copy number 8: 1; copy number 37: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:43,169,008–43,172,805, 1 gene, copy number 37: CRYAA.
- chr21:46,690,764–46,691,226, 1 gene, copy number 5: RPL23AP4.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.
- chr22:18,906,028–18,947,732, 3 genes, copy number 6 (within-gene range 2–6): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 69. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
